Gene-level copy-number profile of tumor specimen ALCH-B1ZQ-TTP1-A from ALCHEMIST case ALCH-B1ZQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.7 years (24,728 days).
Specimen ALCH-B1ZQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04889cc0-f1a4-4287-bea7-efa38fde480c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1ZQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/b04aedd6-df28-457f-8239-10ce0de8a68e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 3,411; copy number 2: 54,431; copy number 3: 328; copy number 4: 86; copy number 5: 18; copy number 6: 11; copy number 7: 1; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,824,605–12,831,410, 1 gene (within-gene range 0–2): PRAMEF11.
- chr1:12,847,377–12,928,253, 7 genes (within-gene range 0–5): HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P.
- chr2:232,649,849–232,650,136, 1 gene (within-gene range 0–2): RN7SL359P.
- chr3:75,415,070–75,435,110, 2 genes: ALG1L6P, FAM86DP.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr5:139,772,528–139,775,472, 2 genes: AC008667.3, AC008667.4.
- chr6:34,466,061–34,576,656, 3 genes: PACSIN1, SPDEF, IFITM3P3.
- chr7:57,817,601–57,837,046, 8 genes: AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:63,567,743–63,621,169, 2 genes: TNRC18P2, MIR4283-2.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:123,356,170–123,402,603, 2 genes (within-gene range 0–3): CRB2, MIR601.
- chr9:130,265,882–130,434,123, 2 genes (within-gene range 0–1): HMCN2, RN7SL665P.
- chr9:130,664,594–130,682,986, 1 gene: PRDM12.
- chr9:130,902,438–130,945,520, 2 genes: FIBCD1, AL161733.1.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr11:70,398,404–70,436,584, 1 gene (within-gene range 0–2): CTTN.
- chr11:70,477,277–70,604,859, 2 genes (within-gene range 0–1): AP001271.1, AP001271.2.
- chr11:70,646,165–70,706,068, 3 genes (within-gene range 0–1): SHANK2-AS2, Y_RNA, AP000590.1.
- chr12:109,713,825–109,833,406, 3 genes (within-gene range 0–2): FAM222A, FAM222A-AS1, TRPV4.
- chr13:112,056,845–112,108,015, 4 genes: SOX1-OT, SOX1, AL356961.1, LINC00404.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr15:77,660,052–77,668,074, 1 gene (within-gene range 0–1): LINGO1-AS2.
- chr16:2,456,252–2,464,963, 3 genes (within-gene range 0–2): AC106820.5, TEDC2, MIR6768.
- chr16:89,906,157–89,968,060, 6 genes (within-gene range 0–1): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8.
- chr16:90,004,871–90,044,975, 3 genes (within-gene range 0–2): DBNDD1, GAS8, GAS8-AS1.
- chr17:22,266,395–22,332,410, 4 genes: AC138761.1, AC138761.2, FAM27E5, AC087575.1.
- chr19:361,747–376,026, 1 gene: THEG.
- chr19:1,505,022–1,513,604, 1 gene: ADAMTSL5.
- chr19:1,508,375–1,508,963, 1 gene: AC027307.1.
- chr20:63,941,465–63,941,544, 1 gene (within-gene range 0–2): MIR1914.
- chr20:64,049,836–64,101,162, 7 genes: TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3.
- chr20:64,105,820–64,107,171, 1 gene: NPBWR2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:150,000,046–150,053,142, 3 genes, copy number 5 (within-gene range 2–5): HMGXB3, AC011406.1, RPS20P4.
- chr9:60,914,407–60,964,196, 5 genes, copy number 6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:136,612,024–136,617,181, 1 gene, copy number 5: LINC01451.
- chr9:136,712,572–136,729,855, 7 genes, copy number 5: DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5.
- chr9:136,754,386–136,800,595, 5 genes, copy number 5–6 (within-gene range 3–6): LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3.
- chr9:137,048,107–137,054,061, 2 genes, copy number 6: ENTPD2, AL807752.4.
- chr9:137,077,517–137,084,539, 1 gene, copy number 9: UAP1L1.
- chr14:99,397,748–99,535,044, 3 genes, copy number 5 (within-gene range 1–5): SETD3, RNU6-91P, CCNK.
- chr15:77,984,036–78,077,724, 1 gene, copy number 5 (within-gene range 1–5): TBC1D2B.
- chr19:1,039,997–1,065,572, 1 gene, copy number 5: ABCA7.
- chr19:1,597,169–1,652,615, 2 genes, copy number 5–7 (within-gene range 2–7): UQCR11, TCF3.

Autosomal genes at a single copy (total copy number 1): 1,727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
